Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NU, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NU-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

Year-old with long history of Barrett's esophagus, chronic GERD and large hiatal hernia. Surveillance endoscopy - ulcerative esophagitis with rare atypia with possible myelodysplasia.

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus." Specimen consists of a 2.1 cm long segment of distal esophagus that is 3.2 cm in internal circumference. There is a 5.2 cm in length x 6.3 x 1.3 cm portion of adherent cardiac stomach. The adventitia is pink-tan with the serosa being a smooth pink-tan. The mucosa of the esophagus is a gray-white. The specimen has been previously incised. The esophageal gastric junction is ill-defined in focal areas with areas of gray-white mucosa located within the gastric mucosa. The gastric mucosa is predominantly rugated tan and is also remarkable for focal areas of pink-tan possible erosions. These erosions range from 0.2 x 0.2 cm to 0.5 x 0.5 cm. The nests of the gray-white tissue range up to 0.3 cm each. These areas are located 2.3 cm away from the distal margin which is the closest margin.

1A-D. Esophageal gastric junction.

1E. White nests of tissue.

1F-G. Gastric erosions.

1H-I. Largest erosion.

2. "Cervical esophageal margin." Specimen consists of a portion of pink-tan tissue, 3.2 cm in length x 2.2 cm in diameter. The mucosa is gray-tan and is folded. One margin has been stapled and the opposite margin is opened. The stapled margin is inked.

2A. Margins.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

If adenocarcinoma, it is arising in: Barrett's mucosa.

Depth of invasion: Muscularis propria.

Number of positive lymph nodes, the total number sampled is irrelevant: 0/0.

Extranodal metastasis: Unknown.

ICD-O-3
Adenocarcinoma NOS 8463
Site: ^{distal} Esophagus, distal third
^{path} Gastroesophageal junction
C15.5
C16.0
gn 1/17/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Pattern of invasion: Infiltrative.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T2 Nx Mx.

PROCEDURE:

VERIFIED BY:

1 & 2. Esophagus, resection: Poorly-differentiated adenocarcinoma, invading into the muscularis propria, 1.5 cm. Margins negative. Please see template for details.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file e9e22c5a-15a6-4c8c-98f2-8c737b05d009 (TCGA-L5-A8NU.C6B7F4EC-9873-41F8-BD83-BBC419DF76CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).